Gene-level copy-number profile of tumor specimen TCGA-85-8287-01A from TCGA case TCGA-85-8287, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.3 years (26,401 days).
Specimen TCGA-85-8287-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3aee26ea-7a03-4102-b3e2-3da3730eba89.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8287-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cdf8cec-3f5e-4022-bd75-984be7a19855

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 466; copy number 2: 142; copy number 3: 24,216; copy number 4: 15,419; copy number 5: 6,264; copy number 6: 8,671; copy number 7: 1,600; copy number 8: 1,368; copy number 9: 269; copy number 10: 851; copy number 11: 94; copy number 12: 185; copy number 15: 52; copy number 16: 2; copy number 17: 3; copy number 23: 6; copy number 24: 1; copy number 25: 46; copy number 26: 21; copy number 27: 41; copy number 34: 18; copy number 36: 11; copy number 42: 7; copy number 44: 40; copy number 45: 12; copy number 50: 3; copy number 60: 2; copy number 78: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8287-01A-11D-2292-01): tumor purity 0.34, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,638 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:50,829,442–63,827,843, 183 genes, copy number 7–23 (within-gene range 4–23) (broad region; genes not listed).
- chr2:112,973,203–113,704,078, 34 genes, copy number 9 (within-gene range 6–9): IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8, AC016745.1, IGKV1OR2-108, AC016745.2, CBWD2, FOXD4L1, LINC01961, PGM5P4-AS1, PGM5P4, FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P.
- chr3:86,125,216–90,261,708, 38 genes, copy number 10–12: AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:53,377,839–54,295,272, 1 gene, copy number 34 (within-gene range 5–34): AC058822.1.
- chr4:53,899,871–56,821,742, 74 genes, copy number 25–36 (broad region; genes not listed).
- chr4:62,510,469–64,611,888, 15 genes, copy number 17–60: HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28.
- chr4:68,877,626–71,030,914, 72 genes, copy number 8–44 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7–10 (broad region; genes not listed).
- chr6:73,523,618–90,587,072, 241 genes, copy number 7–10 (within-gene range 6–10) (broad region; genes not listed).
- chr7:27,830,573–28,180,795, 1 gene, copy number 11 (within-gene range 4–11): JAZF1.
- chr7:28,118,113–36,320,479, 150 genes, copy number 9–11 (broad region; genes not listed).
- chr7:36,337,667–36,337,778, 1 gene, copy number 9: Y_RNA.
- chr7:47,740,202–77,329,533, 623 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).
- chr7:81,335,106–109,326,315, 521 genes, copy number 8–15 (broad region; genes not listed).
- chr8:39,106,990–39,284,917, 1 gene, copy number 7 (within-gene range 4–7): ADAM32.
- chr8:39,309,909–43,674,591, 104 genes, copy number 7 (broad region; genes not listed).
- chr8:51,257,688–52,745,843, 19 genes, copy number 8: AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:53,388,701–113,436,939, 918 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:124,474,880–145,066,685, 384 genes, copy number 7–8 (within-gene range 3–8) (broad region; genes not listed).
- chr11:67,266,473–70,436,584, 128 genes, copy number 7–78 (within-gene range 4–78) (broad region; genes not listed).
- chr11:70,477,277–70,477,592, 1 gene, copy number 78: AP001271.1.
- chr15:77,984,036–78,077,724, 1 gene, copy number 12 (within-gene range 3–12): TBC1D2B.
- chr15:78,077,808–78,552,417, 21 genes, copy number 12 (within-gene range 4–12): SH2D7, SNORA63, CIB2, IDH3A, AC090260.1, ACSBG1, AC090607.3, DNAJA4, WDR61, AC090607.4, AC090607.2, AC090607.1, AC090607.5, AC011270.2, CRABP1, AC011270.1, IREB2, AC027228.1, HYKK, AC027228.3, PSMA4.
- chr15:87,038,717–89,631,056, 49 genes, copy number 8–27: AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1, NTRK3, MED28P6, NTRK3-AS1, MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2, LINC01586, MIR1179, MIR7-2, MIR3529, AEN, ISG20, AC103982.1, ACAN, HAPLN3, MFGE8, AC067805.1, KRT18P47, AC107954.1, AC013565.2, AC013565.1, AC013565.3, ABHD2, RNU7-195P, HMGB1P8, AC124068.1, RLBP1, FANCI, POLG, MIR6766, AC124068.2, AC133637.1, AC133637.2, MIR9-3HG, MIR9-3, RHCG, LINC00928, AC013391.3, AC013391.2, TICRR, AC013391.1.
- chr15:90,001,324–90,082,206, 1 gene, copy number 24 (within-gene range 3–26): ZNF710.
- chr15:90,074,512–90,349,437, 21 genes, copy number 26: ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3.
- chr16:56,904,264–56,983,845, 6 genes, copy number 11: MIR6863, RPS24P17, HERPUD1, AC012181.2, AC012181.1, CETP.
- chr17:76,950,317–82,418,637, 231 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr20:48,821,688–51,131,667, 67 genes, copy number 7 (broad region; genes not listed).
- chr22:29,788,609–30,421,771, 22 genes, copy number 7 (within-gene range 4–7): ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215.

Autosomal genes at a single copy (total copy number 1): 466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
